Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8329, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8329-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

1: SP: Left kidney and adrenal gland

2: SP: Para-aortic lymph nodes

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, LEFT; EXCISION:
- RENAL CELL CARCINOMA, CHROMOPHOBE CELL TYPE.
- THE TUMOR'S GREATEST DIAMETER IS 5.2 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL NEPHRITIS.
- THE ADRENAL GLAND IS UNREMARKABLE.
- 2) LYMPH NODE, PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SPECIMENS (AND/OR OTHER MATERIAL) AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

[REDACTED]

[REDACTED]

- 1) The specimen is received fresh and is labeled left kidney and adrenal gland. It consists of a kidney, with perinephric fat, portion of ureter and hilar vessels. The adrenal gland is present. The overall dimensions of the specimen are 18x 10 x 5.5cm. The kidney weighs 495 grams. The renal capsule strips easily. The kidney measures 15x 6x4.5cm. Within the upper pole of the kidney there is a yellow tan necrotic mass measuring 5.2 in greatest dimension. The tumor appears to be near the perirenal fat. The remainder of the renal parenchyma exhibits no lesion. The renal pelvis appears not to be involve by tumor. The renal sinus appears not to be involve by tumor. The renal vein appears not to be involve by tumor. The perirenal fat is not involved. The adrenal gland measures 4.2 x 2.6 x 2.0cm and is unremarakable.

[page 2 of 2]
The segment of ureter measures 8 cm in length and is unremarkable.
Representative sections are submitted.

Summary of sections:

T-tumor
TN-tumor and normal
TC-tumor and capsule
NK-normal kidney
RP-renal pelvis
UM-ureteral margin
U-random ureter
VM-vascular margin
AG adrenal gland

2) The specimen is received in formalin, labeled "Para-aortic lymph nodes". It consists of a single piece of fatty tissue measuring 3 x 1.5 x 0.5 cm. Entirely submitted for all of the possible lymph nodes.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Left kidney and adrenal gland

Block	Sect. Site	PCs
1	AG	0
3	NK	0
1	RP	0
5	T	0
2	TC	0
3	TN	0
1	UM	0
1	VM	0

Part 2: SP: Para-aortic lymph nodes

Block	Sect. Site	PCs
2	U	2

Source: NCI Genomic Data Commons file 5e7648bf-a3b3-4f75-9f16-c29fd4a6dde1 (TCGA-KL-8329.86E6CF70-83EE-4701-8F54-52A56BA8C83E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).